TARGET case TARGET-15-SJMPAL043508 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4213bd4c-9d15-4c2f-b84a-f5e933c6d526

Demographics
Sex at birth: female; Age at index: 9 years; Vital status: Dead; Days to death: 1,806 days (4.9 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 9.6 years (3,505 days); Year of diagnosis: 1987; Days to last follow up: 1,806 days (4.9 years).

Follow-up (1 entry)
- Days to follow up: 1,806 days (4.9 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,806; Year of follow up: 1992.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 9.6 ×10³/µL.

Biospecimens (5 samples)
- Samples TARGET-15-SJMPAL043508-04A, TARGET-15-SJMPAL043508-04B (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Samples TARGET-15-SJMPAL043508-09A, TARGET-15-SJMPAL043508-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL043508-14A.1: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 1806
- Protocol: St. Jude
- WBC at Diagnosis: 9.6
- Initial Therapy: AML
- Karyotype: 46,X,-X,+8,der(16)t(1;16)(q21;q13)[18]/46,XX[4]
- WHO ALAL Classification: B/M
- WHO Dx: B/M
- WHO RL1: B/M
- WHO RL2: B-ALL
